Gene-level copy-number profile of tumor specimen TCGA-GV-A3QG-01A from TCGA case TCGA-GV-A3QG, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 65.3 years (23,847 days).
Specimen TCGA-GV-A3QG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.70636175-fca8-4d05-acfd-0e4c48e8f92f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GV-A3QG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/42e4893f-6928-4e0f-9195-ae4acf350e79

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 7,512; copy number 2: 41,546; copy number 3: 8,667; copy number 4: 1,550; copy number 5: 63; copy number 7: 473.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GV-A3QG-01A-11D-A21Y-01): tumor purity 0.46, ploidy 2.13, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 536 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:26,598,600–28,180,795, 63 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr13:77,535,674–114,337,626, 473 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,134. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
